FM case AD2497 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Miscellaneous Tumors.
https://portal.gdc.cancer.gov/cases/7d55b031-eed9-4cb1-8035-5f8e755344e0

Male, 21.6 years: Chordoma, NOS (ICD-O-3 9370/3); metastasis biopsied or resected from the vertebral column. Tumor nuclei on the sequenced sample's slide: 40% (pathologist estimate recorded by GDC). Sample type: Metastatic.
